FM case AD4660 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/9d14d035-6e69-458f-afda-e52889203a62

Female, 53.7 years: Sarcomatoid carcinoma (ICD-O-3 8033/3) of the lung; metastasis biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
